CCDI case PBCJEN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/114db527-4052-4de7-889e-b79b85b3f7dd

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Signet ring cell carcinoma: ICD-O-3 morphology code: 8490/3; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 15.6 years (5,709 days).

Biospecimens (3 samples)
- Sample 0DTC5K: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTC5S: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTC5Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
